Somatic mutation profile of tumor specimen TARGET-10-PARFPJ-09A (aliquot TARGET-10-PARFPJ-09A-01D) from TARGET case TARGET-10-PARFPJ, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,348 days).
Specimen TARGET-10-PARFPJ-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c6d2b9a6-c89a-4834-9a0a-5e60b4e5a611.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARFPJ-14A (Bone Marrow Normal), aliquot TARGET-10-PARFPJ-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dcfac2e3-a0ff-4e03-a304-d4b65176fdd2

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.7909C>T p.R2637* (on ENST00000358273 / NM_001042492.3; = p.R2616* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 117/167 reads (70%) | catalogued as rs786201367, CM950853, COSV62195872; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- STAT5B | c.1924A>C p.N642H | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.949); catalogued as rs938448224, COSV53180204; ClinVar: pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BCL11B | c.1360C>A p.P454T (on ENST00000357195 / NM_001282237.2; = p.P383T on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61735839; called by muse, mutect2, varscan2
- DCST1 | c.1808C>T p.A603V | Missense Mutation (SNP) | VAF 65/220 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.013); catalogued as COSV55059738; called by muse, mutect2, varscan2
- NOTCH1 | c.5039T>A p.I1680N | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53025693, COSV53032125, COSV53096766; called by muse, mutect2
- NRXN3 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 44/119 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.038); catalogued as rs747991755, COSV55322252; called by muse, mutect2, varscan2
- WDR59 | c.2794C>T p.R932W | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs762127264, COSV50932997; called by muse, mutect2
- ZNF423 | c.1523G>A p.R508H (on ENST00000563137 / NM_001379286.1; = p.R500H on NM_015069.4) | Missense Mutation (SNP) | VAF 56/160 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs779795080, COSV52190291; called by muse, mutect2, varscan2
- MDGA1 | c.579+86C>T | Intron (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
